Gene-level copy-number profile of tumor specimen TCGA-HT-A5RB-01A from TCGA case TCGA-HT-A5RB, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 24.1 years (8,820 days).
Specimen TCGA-HT-A5RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.128f2267-141a-4664-a560-8a50ae8181dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A5RB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/08f2a3e4-8fca-420d-9509-f9485e30ea23

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,659; copy number 2: 55,930; copy number 3: 226.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-A5RB-01A-11D-A288-01): tumor purity 0.84, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
